Somatic mutation profile of tumor specimen MP2PRT-PAUJVW-TMP1-A (aliquot MP2PRT-PAUJVW-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUJVW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,093 days).
Specimen MP2PRT-PAUJVW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9624495a-9e55-4222-8983-8c6036f3dd6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJVW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJVW-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2acf455-e25d-4f32-8a1e-2479c9ab6647

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HUWE1 | c.12020G>A p.R4007H | Missense Mutation (SNP) | VAF 185/461 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1556914313; called by muse, mutect2, varscan2
- KIF18B | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 51/340 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs754303624; called by muse, mutect2, varscan2
- LCN1 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV55019324; called by muse, mutect2, varscan2
- MXRA5 | c.3617T>C p.V1206A | Missense Mutation (SNP) | VAF 44/634 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV54224369; called by muse, mutect2
- PIEZO2 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 150/358 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs749474073, COSV57434363; called by muse, mutect2, varscan2
- TPBG | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1254806075; called by muse, mutect2, varscan2
- FIGNL2 | c.1708G>C p.A570P | Missense Mutation (SNP) | VAF 59/879 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); called by muse, mutect2
- SPATA4 | c.221A>C p.D74A | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- ANXA1 | c.501C>T p.D167= | Silent (SNP) | VAF 142/348 reads (41%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.264C>T p.R88= | Silent (SNP) | VAF 315/736 reads (43%) | catalogued as COSV51539621, COSV99289917; called by muse, mutect2, varscan2
- KIAA1614 | c.1632C>T p.D544= | Silent (SNP) | VAF 32/672 reads (5%) | catalogued as rs1052237252, COSV62550954; called by muse, mutect2
- NSG2 | c.45G>A p.P15= | Silent (SNP) | VAF 36/565 reads (6%) | catalogued as rs202053280, COSV57458742; called by muse, mutect2
